Surgical pathology report (de-identified scan), TCGA case TCGA-55-8089, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8089-01A (Primary Tumor).

[page 1 of 2]
Sex: [REDACTED]
D.O.B.: [REDACTED]
MRN: [REDACTED]
Ref P: [REDACTED]

SPECIMEN INFORMATION

Collected: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

Accession #: [REDACTED]
Acct / Reg [REDACTED]

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Lymph nodes, level 12, right upper lobe, excision:
Anthracosis and reactive changes, lymph node fragments.
Negative for malignancy.

B. Lymph nodes, level 10, right upper lobe, excision:
Anthracosis and reactive changes, lymph node fragments.
Negative for malignancy.

C. Lung, right upper lobe, resection:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Histologic grade: III (poorly differentiated).
3. Tumor site: Peripheral, subpleural.
4. Tumor focality: Unifocal.
5. Tumor size: 1.8 x 1.7 x 1.3 cm.
6. Visceral pleural invasion: Not identified.
7. Lymphovascular space invasion: Not identified.
8. Tumor extension: None.
9. Treatment effect: Not identified.

Surgical Margin Status:

1. Tumor distance from bronchial margin: 8.0 cm.
2. Tumor distance from parenchymal (stapled) margin: 4.0 cm.
3. Tumor distance from pleural surface: <0.1 cm.

Lymph Node Status:

1. Total number of lymph nodes received: At least eleven (see comment).
2. Total number of lymph nodes containing metastatic carcinoma: Zero (0/11).

Other:

1. pTNM stage: pT1a, N0.

D. Lymph nodes, level 9, right, biopsy:

Anthracosis and reactive change.
Negative for malignancy, one node (0/1).

E. Lymph nodes, level 2/4, right, excision:

Anthracosis and reactive change.
Negative for malignancy, lymph node fragments.

Electronic Signature: [REDACTED]

COMMENTS:

An accurate lymph node count is not possible, as several sites were received as multiple individual fragments. The number eleven is a minimum possible number.

The malignancy is poorly differentiated, and associated peripherally with an area of apparent scarring. Focally, there is a rare suggestion of gland formation. No squamous differentiation is identified. Accordingly, a series of immunohistochemical stains is performed. Sections are examined along with appropriately staining positive and negative controls, with the following results:

CK5/6 - negative.
CK7 - strongly and diffusely positive.
TTF-1 - negative.
p63 - negative.

[page 2 of 2]
The staining pattern favors the diagnosis of poorly differentiated adenocarcinoma.

No prior material is identified in our files for review and comparison, and this appear to represent a new pulmonary adenocarcinoma diagnosis. Accordingly, studies of the EGFR/KRAS/ALK mutation cascade have been requested, and will be reported as an addendum.

Sections have also been reviewed

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: ■ year old male right upper lung cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Level 12 lymph node right upper lobe
- B. Right level 10 lymph node
- C. Right upper lobe
- D. Right level 9 lymph node
- E. Right level 2/4

SPECIMEN DATA

GROSS DESCRIPTION:

Specimen is received in five formalin filled containers labeled with the patient's name

- A. Additionally labeled level 12 lymph node right upper lobe and contains a 2.8 x 1.2 x 0.7 cm aggregate of dark brown to black rubbery soft tissue consistent with anthracotic lymph nodes. The specimen is wrapped in tissue paper and entirely submitted in cassette A labeled
- B. Additionally labeled right level 10 lymph node and contains a 2.8 x 1.4 x 1.0 cm aggregate of yellow-gray rubbery, irregular soft tissue consistent with anthracotic lymph nodes. The specimen is wrapped in tissue paper and entirely submitted in cassette B labeled
- C. Additionally labeled right upper lobe and contains a 17.0 x 11.0 x 6.0 cm purple-gray anthracotic lung lobe. A 1.5 cm in length by 1.8 cm in diameter stapled bronchial margin is identified. The bronchus is opened to reveal a pink-tan glistening endothelium and contains blood tinged mucus. No discrete endobronchial lesions are identified. Adjacent to the bronchus are segments of clamped vasculature as well as four staple lines ranging from 0.7 up to 3.7 cm in greatest dimension. All staple lines are removed to reveal two areas of exposed parenchymal margin 6.5 x 4.5 cm and 2.0 x 1.5 cm. Both of these are adjacent to the aforementioned bronchus and vasculature. The specimen is serially sectioned to reveal a 1.8 x 1.7 x 1.3 cm gray-white nodule that approaches to within <0.1 cm of the inked pleura to within 4.0 cm of the closest (largest) exposed parenchymal margin, 8.0 cm of the bronchial margin and 5.5 cm of the closest vascular margin. The remainder of the cut surface is comprised of congested red-pink spongy parenchyma. No additional lesions are identified. On palpation, six ill defined black parabronchial nodules are identified consistent with anthracotic lymph nodes. These range from 0.3 to 0.6 cm in greatest dimension. Representative sections are submitted in cassettes C1-9 labeled ■■■■■■ signated as follows: 1--bronchial and vascular margins, en face; 2-5--entire mass to inked pleura, perpendicular; 6--perpendicular parenchymal margin closest to mass; 7--perpendicular parenchymal margin furthest from mass; 8--uninvolved parenchyma; 9--whole possible lymph nodes. Additionally, a yellow green and blue cassette are submitted for Genomics research each labeled ■■■■■■.
- D. Additionally labeled right level 9 lymph node and contains a 0.6 cm black rubbery nodule consistent with anthracotic lymph node. The specimen is wrapped in tissue paper and entirely submitted in cassette D labeled
- E. Additionally labeled right level 2/4 and contains a 2.3 x 1.8 x 1.0 cm aggregate of yellow-gray rubbery, nodular soft tissue consistent with lymph nodes. The specimen is wrapped in tissue paper and entirely submitted in cassette E labeled

Source: NCI Genomic Data Commons file 79c816c9-c625-4571-8a3d-84b02a7cb9d3 (TCGA-55-8089.AF442CEA-76DF-4233-B3D6-134B1E91C607.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).